Somatic mutation profile of tumor specimen C3L-00904-01 (aliquot CPT0007740009) from CPTAC case C3L-00904, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 71.7 years (26,190 days).
Specimen C3L-00904-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d32388c-d764-44b9-9d90-2c077e4f9eaa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00904-31 (Blood Derived Normal), aliquot CPT0002920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2fefdea-aa6f-4912-afca-39e0384493ac

The open-access MAF lists 394 somatic variants for this specimen: 263 protein-altering or splice-affecting, 83 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 225, Silent 83, Intron 26, Nonsense Mutation 17, RNA 10, Frame Shift Del 9, Splice Site 5, 3'UTR 5, 5'Flank 5, Frame Shift Ins 4, Splice Region 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs80357093, CM041688, COSV58800783; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CB | c.3199G>C p.D1067H | Missense Mutation (SNP) | VAF 37/192 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56684065, COSV56687870; called by muse, mutect2, varscan2
- ADAMTS19 | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50742963; called by muse, mutect2, varscan2
- AK9 | c.3446T>C p.I1149T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs368903575; called by muse, mutect2, varscan2
- ARID1B | c.3763G>T p.D1255Y | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99034225; called by muse, mutect2, varscan2
- CASKIN1 | c.2864C>A p.S955* | Nonsense Mutation (SNP) | VAF 36/240 reads (15%) | catalogued as COSV100399921; called by muse, mutect2, varscan2
- CDC14A | c.977+2T>C p.X326_splice | Splice Site (SNP) | VAF 35/133 reads (26%) | catalogued as COSV100324995; called by muse, mutect2, varscan2
- CDHR3 | c.1802C>A p.S601Y | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58415459, COSV58422591; called by muse, mutect2, varscan2
- CDKN2A | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 54/243 reads (22%) | catalogued as COSV58705987; called by muse, mutect2, varscan2
- CEP295 | c.5501T>C p.V1834A | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV100292399; called by muse, mutect2, varscan2
- COL22A1 | c.2678C>A p.P893H | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.977); catalogued as COSV57350832; called by muse, mutect2, varscan2
- COL27A1 | c.1999G>T p.G667C | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61928315; called by muse, mutect2, varscan2
- COL5A2 | c.1465G>A p.G489S | Missense Mutation (SNP) | VAF 56/526 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777609980; called by muse, mutect2, varscan2
- CRB1 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 94/640 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1240136255, COSV66330881; called by muse, mutect2, varscan2
- CST1 | c.79G>A p.D27N | Missense Mutation (SNP) | VAF 94/425 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs754461118; called by muse, mutect2, varscan2
- CTNND2 | c.2654G>A p.R885Q | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1038934049; called by muse, mutect2, varscan2
- CTNND2 | c.2177G>C p.G726A | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58924817, COSV58934827; called by muse, mutect2, varscan2
- DCAF13 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as COSV52571313; called by muse, varscan2
- DNAH7 | c.6578C>G p.S2193* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | catalogued as COSV100414090; called by muse, mutect2, varscan2
- EDIL3 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56924916; called by muse, mutect2, varscan2
- EFNA3 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 113/422 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016227847; called by muse, mutect2, varscan2
- ENAM | c.1102C>G p.R368G | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68535963; called by muse, mutect2, varscan2
- ENAM | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV68535624; called by muse, mutect2, varscan2
- ENPP1 | c.1442G>C p.R481P | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as CM164554; called by muse, varscan2
- FOXD4 | c.622G>T p.G208* | Nonsense Mutation (SNP) | VAF 187/797 reads (23%) | catalogued as COSV100071090; called by muse, mutect2, varscan2
- GSTCD | c.1799G>A p.R600Q (on ENST00000360505 / NM_001031720.3; = p.R513Q on NM_024751.3) | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750695972, COSV100853827; called by muse, mutect2, varscan2
- GUCY2EP | n.1353C>G | Splice Region (SNP) | VAF 16/89 reads (18%) | catalogued as rs1369144306; called by muse, mutect2, varscan2
- GYS2 | c.1745G>C p.R582T | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM068264; called by muse, mutect2, varscan2
- HEPH | c.529G>T p.D177Y (on ENST00000343002; = p.D231Y on NM_138737.5) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57967043; called by muse, mutect2, varscan2
- IGKV1-8 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 106/572 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs761429588; called by muse, mutect2, varscan2
- ITPRID2 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.051); catalogued as rs770372418; called by mutect2, varscan2
- KCNH7 | c.1642G>C p.G548R | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100037960; called by muse, mutect2, varscan2
- KCNJ3 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 118/620 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV54532081; called by muse, mutect2, varscan2
- KCNJ4 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 80/422 reads (19%) | catalogued as COSV57856828; called by muse, mutect2, varscan2
- KDF1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 61/527 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as rs771599585, COSV57670773; called by muse, mutect2, varscan2
- KRTAP10-1 | c.20C>G p.S7C | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59951134; called by muse, mutect2
- MAP2 | c.3130G>T p.G1044C | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV52311005; called by muse, mutect2, varscan2
- MAP3K20 | c.2142C>G p.F714L | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as COSV100919628; called by muse, mutect2, varscan2
- MCOLN2 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 53/260 reads (20%) | catalogued as rs867348720; called by muse, mutect2, varscan2
- MTOR | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 84/476 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs751497868; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.22178C>T p.S7393F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV67459374; called by muse, mutect2, varscan2
- MYH4 | c.5026G>A p.A1676T | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV55122491; called by muse, mutect2, varscan2
- MYH9 | c.5830G>A p.D1944N | Missense Mutation (SNP) | VAF 78/510 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as rs777918996; called by muse, mutect2, varscan2
- NBPF6 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 33/295 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.725); catalogued as rs1414239962; called by muse, mutect2, varscan2
- OBSCN | c.16679G>A p.G5560E | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1480896880, COSV52738673; called by muse, mutect2, varscan2
- OPRK1 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV55571483; called by muse, mutect2, varscan2
- OR1C1 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs770848084, COSV68715741; called by muse, mutect2, varscan2
- OR1Q1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs756129489, COSV52917127; called by muse, mutect2, varscan2
- OR2AT4 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as rs1209868088, COSV100532373; called by muse, mutect2, varscan2
- OR4D2 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 95/499 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV73459883; called by muse, mutect2, varscan2
- OR5F1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as COSV99558538; called by muse, varscan2
- PADI2 | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1357168541; called by muse, mutect2, varscan2
- PAPPA | c.2845G>T p.D949Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100075723; called by muse, mutect2, varscan2
- PATE2 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100653472; called by muse, mutect2, varscan2
- PCDH18 | c.1408T>C p.Y470H | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265245762; called by muse, mutect2, varscan2
- PCLO | c.13167G>C p.R4389S | Missense Mutation (SNP) | VAF 54/307 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100426555, COSV61677226; called by muse, mutect2, varscan2
- PIK3C2B | c.1633G>A p.A545T | Missense Mutation (SNP) | VAF 60/438 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.175); catalogued as rs1005409129, COSV65810807; called by muse, mutect2, varscan2
- PIK3R3 | c.41A>T p.D14V | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV53107771; called by muse, mutect2, varscan2
- PLCB1 | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV62049598; called by muse, mutect2, varscan2
- POM121L12 | c.325G>T p.G109W | Missense Mutation (SNP) | VAF 66/309 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68693045, COSV68694286; called by muse, mutect2, varscan2
- PRAMEF4 | c.348G>C p.M116I | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs1261917458; called by muse, mutect2, varscan2
- PROS1 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128591, CM163583, COSV67776400; called by muse, mutect2, varscan2
- PRRX2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1367539391; called by muse, mutect2, varscan2
- REM1 | c.365C>A p.T122K | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52429909; called by muse, mutect2, varscan2
- RPA4 | c.310G>C p.A104P | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100234319; called by muse, mutect2, varscan2
- SEMA3C | c.1717A>G p.R573G | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.146); catalogued as COSV99543016; called by muse, mutect2
- SLC17A2 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 19/272 reads (7%) | catalogued as rs1442616349; called by muse, mutect2
- SLC9A4 | c.1508C>A p.A503D | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99762769; called by muse, mutect2, varscan2
- SLITRK1 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 66/378 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV65676412; called by muse, mutect2, varscan2
- SMAD9 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs752573950, COSV63205176; called by muse, mutect2, varscan2
- SPAG11B | c.65C>G p.S22W | Missense Mutation (SNP) | VAF 96/1303 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.984); catalogued as rs758891774, COSV52499535; called by muse, mutect2
- STX19 | c.280A>G p.I94V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs148513515; called by muse, mutect2, varscan2
- TIE1 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs776542301; called by muse, varscan2
- TP53 | c.929_930insT p.N311Qfs*26 | Frame Shift Ins (INS) | VAF 79/375 reads (21%) | catalogued as COSV53235861, COSV53680057; called by mutect2, pindel, varscan2
- TPST2 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV100113993; called by muse, mutect2, varscan2
- TRHDE | c.2130+1G>T p.X710_splice | Splice Site (SNP) | VAF 41/140 reads (29%) | catalogued as COSV53845632; called by muse, mutect2, varscan2
- TRIM41 | c.1045G>C p.A349P | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.554); catalogued as COSV59318582; called by muse, mutect2, varscan2
- TRIM71 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 107/470 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1374260030; called by muse, mutect2, varscan2
- TRPS1 | c.1703C>G p.P568R (on ENST00000220888 / NM_001330599.2; = p.P581R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55228185; called by muse, mutect2, varscan2
- TYR | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 80/424 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs765187494, COSV54477712; called by muse, mutect2, varscan2
- TYR | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs760149792, COSV54469021; called by muse, mutect2, varscan2
- USP29 | c.209G>C p.S70T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV54238070; called by muse, mutect2, varscan2
- VWC2 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 59/417 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61487339; called by muse, mutect2, varscan2
- YIPF7 | c.388dup p.T130Nfs*18 | Frame Shift Ins (INS) | VAF 19/104 reads (18%) | catalogued as rs760315752; called by mutect2, pindel, varscan2
- ZFP57 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 133/434 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs1277272289; called by muse, mutect2, varscan2
- ZIC1 | c.569C>G p.A190G | Missense Mutation (SNP) | VAF 77/474 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51558671; called by muse, mutect2, varscan2
- ZNF22 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53585385; called by muse, mutect2, varscan2
- ZNF732 | c.1474C>T p.H492Y | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs879978874; called by muse, varscan2
- ZPBP | c.992G>T p.R331L | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV50422674; called by muse, mutect2, varscan2
- ZSWIM5 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100655957; called by muse, mutect2, varscan2
- AC092143.1 | c.1460G>A p.G487E | Missense Mutation (SNP) | VAF 118/661 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC100868.1 | c.20C>A p.T7N | Missense Mutation (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- ACAP2 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- ACAT1 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- ADAMTS1 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS5 | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ADGRB3 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ADORA1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- AKAP13 | c.4559G>T p.G1520V | Missense Mutation (SNP) | VAF 53/309 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ALKBH1 | c.943A>G p.R315G | Missense Mutation (SNP) | VAF 96/402 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- AMER2 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ANK2 | c.2314G>T p.G772C | Missense Mutation (SNP) | VAF 163/821 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3439A>G p.N1147D | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANKLE2 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ANKRD6 | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO3 | c.716G>C p.G239A | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANOS1 | c.60_61del p.S20Rfs*65 | Frame Shift Del (DEL) | VAF 67/198 reads (34%) | called by mutect2, pindel, varscan2
- APOF | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.013); called by muse, mutect2
- ARC | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ATG9B | c.174T>G p.H58Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); called by muse, mutect2
- ATPSCKMT | c.16+1G>T p.X6_splice | Splice Site (SNP) | VAF 27/132 reads (20%) | called by muse, varscan2
- ATRNL1 | c.997G>T p.V333F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); called by muse, varscan2
- B3GALT6 | c.379G>T p.D127Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BEND2 | c.2107C>G p.L703V | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BTN3A3 | c.544A>T p.T182S | Missense Mutation (SNP) | VAF 28/742 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- CASQ1 | c.141C>A p.D47E | Missense Mutation (SNP) | VAF 164/631 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CCDC150 | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); called by muse, varscan2
- CCDC168 | c.10597dup p.E3533Gfs*22 | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- CCDC88B | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CHRNB3 | c.1131A>T p.K377N | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.428); called by muse, varscan2
- CNTNAP5 | c.2622del p.W874Cfs*37 | Frame Shift Del (DEL) | VAF 76/480 reads (16%) | called by mutect2, pindel, varscan2
- COL22A1 | c.364C>G p.R122G | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- COL5A1 | c.3205G>T p.G1069* | Nonsense Mutation (SNP) | VAF 185/962 reads (19%) | called by muse, mutect2, varscan2
- COL5A1 | c.4159G>T p.G1387W | Missense Mutation (SNP) | VAF 72/456 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPO | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CREB3L3 | c.470C>A p.P157Q | Missense Mutation (SNP) | VAF 83/390 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CROCC | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 50/247 reads (20%) | called by muse, mutect2, varscan2
- CSF2RA | c.43C>A p.H15N | Missense Mutation (SNP) | VAF 118/693 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- CSMD3 | c.5479_5480del p.L1827Vfs*19 (on ENST00000297405 / NM_001363185.1; = p.L1723Vfs*19 on NM_052900.3) | Frame Shift Del (DEL) | VAF 38/219 reads (17%) | called by pindel, varscan2
- CSNK1G1 | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CTRB1 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.191); called by muse, mutect2
- DENND1C | c.297-1G>A p.X99_splice | Splice Site (SNP) | VAF 47/212 reads (22%) | called by muse, mutect2, varscan2
- DEPDC1 | c.1984G>A p.D662N (on ENST00000456315 / NM_001114120.3; = p.D378N on NM_017779.6) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH6 | c.3442C>A p.L1148M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DNAH9 | c.10478G>T p.G3493V | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DOCK5 | c.823A>G p.N275D | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- EARS2 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2
- EMILIN2 | c.2617G>C p.G873R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ERICH3 | c.1618C>G p.P540A | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ESYT2 | c.2107C>G p.P703A (on ENST00000613624; = p.P627A on NM_020728.3) | Missense Mutation (SNP) | VAF 17/329 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2
- F8 | c.4270A>T p.T1424S | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, varscan2
- FAT4 | c.6420dup p.V2141Cfs*6 | Frame Shift Ins (INS) | VAF 31/180 reads (17%) | called by mutect2, pindel, varscan2
- FBXO30 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- FHL2 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2
- FNIP2 | c.1370A>T p.H457L | Missense Mutation (SNP) | VAF 46/316 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.155); called by muse, varscan2
- FOXR2 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAL3ST3 | c.868T>A p.W290R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GBA3 | c.695C>A p.A232E | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GINS3 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 63/418 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- GLYATL3 | c.407del p.S136Ffs*19 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- GREB1L | c.5143G>C p.D1715H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- GRIN2A | c.3438C>A p.D1146E | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRIN2B | c.2764C>G p.L922V | Missense Mutation (SNP) | VAF 298/869 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- GTF2E1 | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HECW2 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 146/670 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- HIPK4 | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- HIVEP2 | c.6781G>A p.E2261K | Missense Mutation (SNP) | VAF 60/341 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HOXA13 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.918); called by mutect2, varscan2
- HRNR | c.2566C>A p.Q856K | Missense Mutation (SNP) | VAF 94/589 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- IGKV2D-40 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 63/802 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2
- IGLV1-50 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- INSRR | c.3787C>A p.P1263T | Missense Mutation (SNP) | VAF 260/899 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IQSEC3 | c.2233C>T p.Q745* (on ENST00000538872 / NM_001170738.2; = p.Q442* on NM_015232.1) | Nonsense Mutation (SNP) | VAF 65/180 reads (36%) | called by muse, mutect2, varscan2
- ITM2A | c.744A>T p.R248S | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- KCNQ2 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 103/482 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KCNU1 | c.1160C>A p.T387K | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- KMT2C | c.11281C>T p.H3761Y | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2
- KRT74 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 101/644 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- LAMA4 | c.2387T>C p.L796P (on ENST00000230538 / NM_001105206.3; = p.L789P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/670 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LOXL3 | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRCH4 | c.1079A>C p.H360P | Missense Mutation (SNP) | VAF 59/427 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MAG | c.92C>A p.S31* | Nonsense Mutation (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- MAGEB10 | c.155G>A p.S52N | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MAGEB16 | c.836del p.P279Qfs*10 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- MED25 | c.2202G>T p.Q734H | Missense Mutation (SNP) | VAF 72/424 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- MEGF8 | c.4135G>T p.A1379S (on ENST00000251268 / NM_001271938.2; = p.A1312S on NM_001410.3) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGAT5B | c.896A>T p.D299V | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRGPRF | c.280T>C p.F94L | Missense Mutation (SNP) | VAF 105/584 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH4 | c.2440G>T p.V814F | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MUC16 | c.12328T>A p.L4110M | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MUC16 | c.9046C>A p.L3016I | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- MUC5AC | c.14522T>C p.I4841T | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT tolerated (0.93); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO3A | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NAP1L3 | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPBWR2 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NPR3 | c.1077A>C p.E359D | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); called by muse, varscan2
- OR10G4 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 63/367 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR10W1 | c.494T>C p.I165T | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- OR1M1 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2A25 | c.589A>G p.M197V | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR2J1 | c.112A>T p.I38L | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T4 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 93/289 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51B4 | c.541G>T p.V181F | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- OSBPL7 | c.2209A>T p.T737S | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- OSBPL9 | c.2185A>G p.K729E | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PCDHGA5 | c.206G>T p.R69I | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PCLO | c.3732A>T p.E1244D | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PEAK1 | c.1102G>T p.G368* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- PHF20 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2
- PIEZO2 | c.2773G>T p.E925* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- POLQ | c.6619A>G p.I2207V | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPM1K | c.30del p.R11Efs*7 | Frame Shift Del (DEL) | VAF 28/168 reads (17%) | called by mutect2, pindel
- PRAMEF12 | c.833T>C p.F278S | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PRIMPOL | c.579del p.L193Ffs*74 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- RBMXL3 | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- REG1A | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- REG1B | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- RNF186 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 54/345 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- RNF217 | c.439C>A p.L147M | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RTCB | c.326C>A p.A109E | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- RYR2 | c.1436T>A p.L479Q | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SCUBE3 | c.2595G>T p.K865N | Missense Mutation (SNP) | VAF 95/299 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SESN3 | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SI | c.4276A>T p.K1426* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- SIPA1L3 | c.4288G>T p.A1430S | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC29A1 | c.29+1G>T p.X10_splice | Splice Site (SNP) | VAF 45/258 reads (17%) | called by muse, mutect2, varscan2
- SLC37A2 | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 90/442 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SMARCA5 | c.2291G>C p.R764P | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SMPD3 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 96/426 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SMPD4 | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SNRPN | c.340G>C p.V114L | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.026); called by muse, mutect2
- SPAG11A | c.65C>G p.S22W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.791); called by mutect2, varscan2
- SPANXN2 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 506/888 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.14); called by muse, varscan2
- SPATA31D1 | c.3305A>T p.Q1102L | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- SPECC1 | c.2897A>T p.N966I | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPRED2 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- ST6GAL2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 47/251 reads (19%) | PolyPhen benign (0.168); called by muse, mutect2, varscan2
- STRA6 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 112/755 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); called by mutect2, varscan2
- SUPT20HL2 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 86/235 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SUPT20HL2 | c.1849G>T p.G617* | Nonsense Mutation (SNP) | VAF 85/233 reads (36%) | called by muse, mutect2, varscan2
- SVOP | c.999del p.L334* | Frame Shift Del (DEL) | VAF 16/206 reads (8%) | called by mutect2, pindel
- SYTL3 | c.1401A>C p.Q467H (on ENST00000611299 / NM_001242394.1; = p.Q399H on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TENM4 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- TESPA1 | c.765C>A p.F255L (on ENST00000316577 / NM_001098815.3; = p.F117L on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TEX2 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- TMC6 | c.536+8G>T | Splice Region (SNP) | VAF 77/534 reads (14%) | called by muse, mutect2, varscan2
- TMCC1 | c.1037G>T p.S346I (on ENST00000393238 / NM_001349268.2; = p.S22I on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/436 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM145 | c.434A>C p.Q145P | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TMEM145 | c.435G>T p.Q145H | Missense Mutation (SNP) | VAF 68/429 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, varscan2
- TNNT2 | c.489+5G>C | Splice Region (SNP) | VAF 69/522 reads (13%) | called by muse, mutect2, varscan2
- TNRC6A | c.4163G>A p.G1388D | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- TONSL | c.3694G>A p.D1232N | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TOX3 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 99/496 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAM1L1 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAPPC10 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 79/335 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49 | c.989C>A p.A330E | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRIP12 | c.3440_3441del p.I1147Sfs*10 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel
- TROAP | c.915G>T p.M305I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, varscan2
- TRPA1 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- TSPAN17 | c.360G>C p.W120C | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TSPY2 | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- TXNRD1 | c.152C>A p.A51D | Missense Mutation (SNP) | VAF 131/569 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TXNRD1 | c.1523A>G p.Y508C (on ENST00000525566 / NM_001093771.3; = p.Y410C on NM_003330.4) | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.203); called by muse, mutect2
- UBE2NL | c.332C>A p.A111D | Missense Mutation (SNP) | VAF 169/295 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- URB1 | c.1212G>T p.Q404H | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WFIKKN2 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 69/419 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWC3 | c.3032G>A p.W1011* | Nonsense Mutation (SNP) | VAF 76/237 reads (32%) | called by muse, mutect2, varscan2
- ZFP91 | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF536 | c.527A>G p.H176R | Missense Mutation (SNP) | VAF 51/395 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF611 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF776 | c.859A>T p.T287S | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ABCC12 | c.2523G>T p.A841= | Silent (SNP) | VAF 98/601 reads (16%) | catalogued as COSV60918577; called by muse, mutect2, varscan2
- ACBD6 | c.546T>C p.N182= | Silent (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- ALLC | c.681A>G p.A227= | Silent (SNP) | VAF 40/261 reads (15%) | called by muse, mutect2, varscan2
- ANK1 | c.3501C>T p.T1167= | Silent (SNP) | VAF 69/378 reads (18%) | called by muse, mutect2, varscan2
- ANKMY2 | c.580C>T p.L194= | Silent (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- AP002512.3 | c.1137G>T p.V379= | Silent (SNP) | VAF 42/250 reads (17%) | called by muse, mutect2, varscan2
- ATP8B1 | c.3615G>A p.R1205= | Silent (SNP) | VAF 111/458 reads (24%) | catalogued as COSV52176998; called by muse, mutect2, varscan2
- B3GALT6 | c.378C>T p.R126= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- CD4 | c.1215C>G p.V405= | Silent (SNP) | VAF 182/551 reads (33%) | called by muse, mutect2, varscan2
- CDHR3 | c.2508C>A p.A836= | Silent (SNP) | VAF 79/544 reads (15%) | called by muse, mutect2, varscan2
- CENPC | c.735T>C p.N245= | Silent (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- CFAP47 | c.4671T>A p.S1557= | Silent (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- CHTF18 | c.1599C>A p.A533= | Silent (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- CIC | c.4698T>C p.S1566= | Silent (SNP) | VAF 18/121 reads (15%) | called by muse, varscan2
- COL25A1 | c.774G>T p.G258= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV67654872; called by muse, mutect2, varscan2
- CORIN | c.3081C>A p.V1027= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- CREB3L3 | c.471A>G p.P157= | Silent (SNP) | VAF 83/390 reads (21%) | called by muse, mutect2, varscan2
- CRISP1 | c.633C>T p.C211= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- CTNND2 | c.2910G>A p.V970= | Silent (SNP) | VAF 166/681 reads (24%) | catalogued as COSV100474932, COSV58890575; called by muse, mutect2, varscan2
- CTRB1 | c.18C>A p.L6= | Silent (SNP) | VAF 23/214 reads (11%) | called by muse, mutect2, varscan2
- CTSL | c.306G>A p.K102= | Silent (SNP) | VAF 37/212 reads (17%) | catalogued as COSV100446806, COSV58246768; called by muse, mutect2, varscan2
- CUX2 | c.3261C>A p.S1087= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- DACH1 | c.78C>A p.S26= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- DEF6 | c.1090C>T p.L364= | Silent (SNP) | VAF 92/296 reads (31%) | called by muse, mutect2, varscan2
- DNAH10 | c.228C>A p.V76= (on ENST00000409039; = p.V15= on NM_207437.3) | Silent (SNP) | VAF 18/221 reads (8%) | called by muse, mutect2
- DNAH8 | c.5109G>A p.L1703= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- DTX1 | c.525C>T p.L175= | Silent (SNP) | VAF 99/261 reads (38%) | catalogued as rs753155493; called by muse, mutect2, varscan2
- DUSP15 | c.663G>A p.L221= | Silent (SNP) | VAF 19/151 reads (13%) | catalogued as rs776364295; called by muse, mutect2, varscan2
- ESCO1 | c.1161G>A p.K387= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV52518921; called by muse, mutect2, varscan2
- F13A1 | c.2085G>T p.V695= | Silent (SNP) | VAF 173/461 reads (38%) | called by muse, mutect2, varscan2
- FAM120C | c.2634C>G p.G878= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs782237927; called by muse, mutect2, varscan2
- FSIP2 | c.16533T>C p.A5511= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- GPR158 | c.324G>A p.L108= | Silent (SNP) | VAF 57/225 reads (25%) | called by muse, mutect2, varscan2
- GRIN2A | c.1191C>A p.S397= | Silent (SNP) | VAF 99/726 reads (14%) | catalogued as COSV58025607, COSV58031282; called by muse, mutect2, varscan2
- GRM6 | c.456G>T p.S152= | Silent (SNP) | VAF 39/160 reads (24%) | called by muse, mutect2, varscan2
- HOXC12 | c.774C>A p.V258= | Silent (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- IGHV1-46 | c.273G>A p.R91= | Silent (SNP) | VAF 129/673 reads (19%) | catalogued as rs782430853; called by muse, mutect2, varscan2
- IGKV1D-8 | c.27C>G p.L9= | Silent (SNP) | VAF 76/492 reads (15%) | called by muse, mutect2, varscan2
- IGKV3-15 | c.57T>C p.T19= | Silent (SNP) | VAF 67/572 reads (12%) | catalogued as rs780013127; called by muse, mutect2, varscan2
- JHY | c.1335A>G p.P445= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- KCNT1 | c.960C>T p.L320= (on ENST00000488444; = p.L339= on NM_020822.3) | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as rs1471908449; called by muse, mutect2, varscan2
- KIAA1549L | c.531G>T p.L177= (on ENST00000321505; = p.L474= on NM_012194.3) | Silent (SNP) | VAF 29/218 reads (13%) | catalogued as rs768498201; called by muse, mutect2, varscan2
- KMT2B | c.2442G>T p.V814= | Silent (SNP) | VAF 26/89 reads (29%) | called by muse, varscan2
- KRTAP10-9 | c.99C>T p.A33= | Silent (SNP) | VAF 94/578 reads (16%) | catalogued as rs1425144579; called by muse, mutect2, varscan2
- LAMA5 | c.7419G>A p.Q2473= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- MLXIP | c.2412G>A p.T804= | Silent (SNP) | VAF 18/332 reads (5%) | catalogued as rs535453580; called by muse, mutect2
- MME | c.2046C>T p.H682= | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- MUC12 | c.15327C>A p.T5109= (on ENST00000379442; = p.T4966= on NM_001164462.1) | Silent (SNP) | VAF 33/154 reads (21%) | called by muse, varscan2
- MYRIP | c.162G>A p.S54= | Silent (SNP) | VAF 79/338 reads (23%) | catalogued as rs568166368, COSV56880561; called by muse, mutect2, varscan2
- NLRC4 | c.1674C>T p.G558= | Silent (SNP) | VAF 24/183 reads (13%) | called by muse, mutect2, varscan2
- NLRP2 | c.1053G>T p.P351= | Silent (SNP) | VAF 72/391 reads (18%) | catalogued as rs199475714; called by muse, mutect2, varscan2
- NRXN2 | c.2170C>A p.R724= | Silent (SNP) | VAF 78/535 reads (15%) | catalogued as COSV99631981; called by muse, mutect2, varscan2
- NUP50 | c.657A>T p.T219= | Silent (SNP) | VAF 65/351 reads (19%) | called by muse, varscan2
- OBSCN | c.2904G>T p.R968= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV52789872; called by muse, varscan2
- OR11A1 | c.123C>T p.I41= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as rs765365352; called by muse, mutect2, varscan2
- OR1I1 | c.990T>C p.A330= | Silent (SNP) | VAF 66/225 reads (29%) | called by muse, mutect2, varscan2
- OR2T27 | c.699G>T p.G233= | Silent (SNP) | VAF 115/242 reads (48%) | called by muse, mutect2, varscan2
- OR4C46 | c.717C>T p.V239= | Silent (SNP) | VAF 30/172 reads (17%) | catalogued as COSV60221524; called by muse, mutect2
- OR5F1 | c.138C>A p.I46= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, varscan2
- OR8B8 | c.630C>A p.P210= | Silent (SNP) | VAF 54/354 reads (15%) | catalogued as COSV60145133; called by muse, mutect2, varscan2
- OR9Q2 | c.915G>T p.L305= | Silent (SNP) | VAF 23/98 reads (23%) | called by muse, varscan2
- PCDH15 | c.4401G>A p.R1467= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs149914859; called by muse, mutect2, varscan2
- PCLO | c.2088G>A p.K696= | Silent (SNP) | VAF 123/648 reads (19%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.11041A>C p.R3681= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- PLCXD2 | c.828G>C p.R276= | Silent (SNP) | VAF 89/415 reads (21%) | catalogued as rs761278099; called by muse, mutect2, varscan2
- PRUNE2 | c.1956G>T p.R652= | Silent (SNP) | VAF 66/272 reads (24%) | catalogued as rs765763473; called by muse, mutect2, varscan2
- RYR2 | c.5253C>A p.I1751= | Silent (SNP) | VAF 78/445 reads (18%) | catalogued as COSV100773285; called by muse, mutect2, varscan2
- SAMSN1 | c.1083C>T p.D361= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs1268485489; called by muse, mutect2, varscan2
- SDK2 | c.6285G>A p.S2095= | Silent (SNP) | VAF 107/564 reads (19%) | catalogued as rs757559673; called by muse, mutect2, varscan2
- SHOX2 | c.534C>A p.G178= (on ENST00000441443 / NM_006884.3; = p.G202= on NM_003030.4) | Silent (SNP) | VAF 79/411 reads (19%) | catalogued as COSV67463804; called by muse, mutect2, varscan2
- SORCS3 | c.1476G>A p.L492= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- SPACA3 | c.621T>A p.T207= | Silent (SNP) | VAF 48/289 reads (17%) | called by muse, mutect2, varscan2
- TAS1R2 | c.828G>A p.S276= | Silent (SNP) | VAF 59/318 reads (19%) | catalogued as rs757949189; called by muse, mutect2, varscan2
- TBC1D10B | c.1608G>A p.S536= | Silent (SNP) | VAF 58/264 reads (22%) | catalogued as rs751167331; called by muse, mutect2, varscan2
- TEX51 | c.597C>T p.T199= | Silent (SNP) | VAF 33/163 reads (20%) | called by muse, mutect2, varscan2
- TLK2 | c.1275A>G p.A425= (on ENST00000326270 / NM_001284333.2; = p.A403= on NM_006852.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/109 reads (17%) | called by muse, mutect2, varscan2
- TNFRSF10B | c.312C>T p.S104= | Silent (SNP) | VAF 78/513 reads (15%) | called by muse, mutect2, varscan2
- UNC13C | c.4170G>C p.G1390= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs772637365, COSV52840893, COSV99524259; called by muse, mutect2, varscan2
- WDFY3 | c.8679C>T p.V2893= | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- WFIKKN2 | c.849G>T p.G283= | Silent (SNP) | VAF 70/426 reads (16%) | called by muse, mutect2, varscan2
- ZBTB49 | c.909C>G p.L303= | Silent (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- ZNF256 | c.1710C>G p.T570= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV56599494; called by muse, mutect2, varscan2
- ZSCAN4 | c.306C>A p.A102= | Silent (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- AC093155.3 | c.871+261G>C | Intron (SNP) | VAF 35/169 reads (21%) | called by muse, mutect2, varscan2
- AC093155.3 | c.871+262G>T | Intron (SNP) | VAF 34/172 reads (20%) | catalogued as rs1041029990; called by muse, mutect2, varscan2
- AC244517.10 | c.36-10638C>T | Intron (SNP) | VAF 37/208 reads (18%) | called by muse, mutect2, varscan2
- ADAM7 | c.2209-1355C>A | Intron (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- AGA | c.*60G>T | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- ARMH1 | c.848-14T>C | Intron (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- BBS9 | c.1017-22112G>T | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- BDKRB2 | c.74+556A>T | Intron (SNP) | VAF 29/237 reads (12%) | called by muse, mutect2, varscan2
- BRAT1 | c.803+24G>A | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- C3orf84 | c.141+162dup | Intron (INS) | VAF 41/153 reads (27%) | called by mutect2, pindel
- C9orf62 | n.322G>A | RNA (SNP) | VAF 24/233 reads (10%) | catalogued as rs760296443; called by muse, mutect2, varscan2
- CHRNA4 | c.1759-34G>T | Intron (SNP) | VAF 141/700 reads (20%) | called by muse, mutect2, varscan2
- CIZ1 | chr9:128191898 del G | 5'Flank (DEL) | VAF 13/68 reads (19%) | catalogued as rs1411483519; called by mutect2, pindel, varscan2
- EML1 | c.519-5271G>T | Intron (SNP) | VAF 26/141 reads (18%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445502 T>C | 3'Flank (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- FOXP2 | c.*417G>A | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- GALNT17 | c.*3_*4del | 3'UTR (DEL) | VAF 28/220 reads (13%) | called by mutect2, pindel, varscan2
- GLIPR1L2 | c.670+84T>C | Intron (SNP) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- HDAC9 | c.-119A>G | 5'UTR (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- IGFL2 | c.19+672C>T | Intron (SNP) | VAF 49/314 reads (16%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.627+492A>G | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1036206995; called by muse, mutect2
- LINC01804 | n.399G>C | RNA (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- MOSMO | chr16:22007659 G>T | 5'Flank (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- NAV3 | c.6519-245C>T | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- NEK9 | c.1528+55A>G | Intron (SNP) | VAF 27/130 reads (21%) | catalogued as rs1483129014; called by muse, mutect2, varscan2
- OR56B3P | n.752T>C | RNA (SNP) | VAF 24/175 reads (14%) | catalogued as rs1417585924; called by muse, mutect2, varscan2
- OSCP1 | c.546+3419G>A | Intron (SNP) | VAF 12/102 reads (12%) | called by muse, varscan2
- PCDHGA3 | c.2425-67288G>A | Intron (SNP) | VAF 12/204 reads (6%) | catalogued as rs1428732557; called by muse, mutect2
- PFKFB1 | chrX:54998434 C>T | 5'Flank (SNP) | VAF 16/52 reads (31%) | catalogued as rs1361366386; called by mutect2, varscan2
- PKD1 | c.7489+18T>G | Intron (SNP) | VAF 114/529 reads (22%) | called by muse, mutect2, varscan2
- POLR3D | chr8:22244995 T>C | 5'Flank (SNP) | VAF 27/156 reads (17%) | catalogued as rs1029283088; called by muse, mutect2, varscan2
- PTPN13 | c.546+517G>T | Intron (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- RCOR3 | c.50-3386G>A | Intron (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.596G>T | RNA (SNP) | VAF 122/768 reads (16%) | called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791071 C>A | 5'Flank (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2
- SET | c.113-1573G>T | Intron (SNP) | VAF 18/152 reads (12%) | catalogued as rs528077107; called by mutect2, varscan2
- SLC25A13 | c.*275G>T | 3'UTR (SNP) | VAF 44/271 reads (16%) | called by muse, mutect2, varscan2
- SMARCB1 | c.363-2281G>A | Intron (SNP) | VAF 82/569 reads (14%) | called by muse, mutect2, varscan2
- SNORD116-24 | n.39G>A | RNA (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2, varscan2
- SNORD116-26 | n.34A>T | RNA (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- SP140 | c.237+16C>A | Intron (SNP) | VAF 25/127 reads (20%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2290G>T | RNA (SNP) | VAF 117/871 reads (13%) | called by muse, mutect2, varscan2
- SSPOP | n.14621G>C | RNA (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- STAU2 | c.1530+24285T>C | Intron (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- SULF1 | c.*81G>A | 3'UTR (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- TTN | c.10360+1732T>G | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- XIST | n.10835C>A | RNA (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- XIST | n.9095G>T | RNA (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
